Somatic mutation profile of tumor specimen TARGET-10-PATRXL-09A (aliquot TARGET-10-PATRXL-09A-01D) from TARGET case TARGET-10-PATRXL, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.8 years (1,767 days).
Specimen TARGET-10-PATRXL-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f0360771-ea31-4b32-bcd9-1490c7a1f274.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATRXL-10A (Blood Derived Normal), aliquot TARGET-10-PATRXL-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aac370aa-ef4d-4c96-8d6a-143183e4ee43

The open-access MAF lists 15 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 3, 3'UTR 2, Nonsense Mutation 2, 3'Flank 1, Splice Region 1, Silent 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATXN1L | c.955_956insATCTCCATATTTA p.R319Hfs*5 | Nonsense Mutation (INS) | VAF 53/68 reads (78%) | catalogued as COSV70235364; called by mutect2, pindel, varscan2
- CDKN1B | c.222C>A p.Y74* | Nonsense Mutation (SNP) | VAF 4/49 reads (8%) | catalogued as COSV57430528; called by muse, mutect2
- HNRNPA1 | c.908-4A>G | Splice Region (SNP) | VAF 33/72 reads (46%) | catalogued as COSV52937510; called by muse, mutect2, varscan2
- LCE2B | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.114); catalogued as rs747416050, COSV64227662; called by muse, mutect2, varscan2
- NAA16 | c.1856G>A p.R619H | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs142294170; called by mutect2, varscan2
- RAB11FIP4 | c.1511G>A p.R504Q | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs769885174, COSV57930520; called by muse, mutect2, varscan2
- SLC25A23 | c.1201C>T p.R401W | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374577579, COSV51190408; called by muse, mutect2, varscan2
- TSPYL2 | c.1437_1438insAGACAACTCT p.E480Rfs*4 | Frame Shift Ins (INS) | VAF 54/62 reads (87%) | catalogued as COSV64921272; called by mutect2, pindel, varscan2
- GALNS | c.1269C>T p.N423= | Silent (SNP) | VAF 30/61 reads (49%) | catalogued as rs148709901; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACAD10 | c.*165G>A | 3'UTR (SNP) | VAF 5/67 reads (7%) | called by muse, mutect2
- CCDC198 | c.307-131C>A | Intron (SNP) | VAF 13/26 reads (50%) | called by muse, mutect2, varscan2
- CDC14B | chr9:96496359 G>A | 3'Flank (SNP) | VAF 6/71 reads (8%) | catalogued as rs965990665; called by muse, mutect2
- CTNND1 | c.2896-61G>T | Intron (SNP) | VAF 14/41 reads (34%) | catalogued as rs1012670018, COSV62382042; called by muse, mutect2, varscan2
- FCRL4 | c.*22C>T | 3'UTR (SNP) | VAF 5/10 reads (50%) | catalogued as rs370897126; called by muse, varscan2
- GINS4 | c.-19-35G>T | Intron (SNP) | VAF 3/28 reads (11%) | called by muse, mutect2
